Surgical pathology report (de-identified scan), TCGA case TCGA-P7-A5NY, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Translational Genomics Research Institute, specimen TCGA-P7-A5NY-05A (Additional - New Primary).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender: F

Physician(s):

Location:

Service:

Billing #:

Accession #: [REDACTED]

Billing Type:

Taken:

Received:

Reported:

Specimen(s) Received

A: Left adrenal pheochromocytoma

B: Right adrenal pheochromocytoma

Pathologic Diagnosis

"A" - Left adrenal, adrenalectomy: Pheochromocytoma (4.2 cm, 37 gm).

"B" - Right adrenal, adrenalectomy: Pheochromocytoma (13.5 cm, 457 gm). ✓

Primary Pathologist:
Electronically Signed

Clinical History

Bilateral pheochromocytoma.

ICD-O-3
Pheochromocytoma 87003
Site Adrenal Gland, C74.9
JL 4/29/13

Gross Description

"A" - Received in formalin labeled "left adrenal pheochromocytoma" is a 37-gram, 6.5 x 5.5 x 3.0 cm adrenal gland. The specimen is inked blue and serially sectioned revealing a well-circumscribed lobulated rubbery nodule (4.2 x 3.3 x 2.2 cm) with a heterogeneous gold-yellow cut surface and a slightly hemorrhagic center. The nodule grossly arises from the adrenal medulla and is <0.1 cm from the nearest inked margin. No other discrete masses or suspicious are grossly identified. The nodule occupies approximately 80% of the adrenal gland volume. The remainder of the adrenal gland has a gold-yellow cortex and a brown-tan medulla. At the periphery of the adrenal gland within the adipose tissue is a 1.2 x 0.4 x 0.3 cm patent unremarkable possible vessel which is uninvolved by the nodule. Representative sections are submitted as labeled: "A1" - nodule and possible vessel, "A2"-A4" - nodule random sections; "A5" - remote from nodule (five cassettes).

* "B" - Received in formalin labeled "right adrenal pheochromocytoma" is a 457-gram, 13.5 x 10.5 x 6.5 cm adrenal gland mass with minimal attached yellow lobulated adipose tissue. The mass is inked green and serially sectioned revealing a cut surface that is 90% solid and 10% cystic. The solid area is heterogeneous red-pink and varies from rubbery to edematous. The cystic component consists of several smooth-walled unilocular cysts (ranging from 0.5 cm to 4.5 cm) filled with brown-red thick fluid. The periphery of the mass contains remnants of adrenal gland cortex and medulla. Additionally identified

[page 2 of 2]
Surgical Pathology Report

within the peripheral adipose tissue is an unremarkable possible vessel (1.0 x 0.3 x 0.3 cm) which is uninvolved by the mass. Representative sections are submitted as labeled: "B1"- "B6" - mass periphery; "B7" - mass centrally; "B8" - vessel (eight cassettes).

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

A: 88307
B: 88307

If immunohistochemistry or in situ hybridization was used the following applies: This test was developed and its performance characteristic determined by [redacted]. It has not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA does not require this test to go through premarket FDA review. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing. All special stains used have adequate controls.

HPA Discrepancy		✓
Print Malignancy Discrepancy		✓
Out of Scope/Primary Noted		✓
Reviewed Initials	BTB	Date Review: 1/18/13

Source: NCI Genomic Data Commons file 6d37cb79-136d-4101-bf71-bd079a749b16 (TCGA-P7-A5NY.C46323FE-B5D9-45D4-B87B-1F8C89E8397D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).